Somatic mutation profile of tumor specimen MP2PRT-PAVFJI-TMP1-A (aliquot MP2PRT-PAVFJI-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVFJI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,130 days).
Specimen MP2PRT-PAVFJI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82e6e7fc-f34c-47d1-9eb7-b30fd5228f00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFJI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFJI-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f306741d-6ec9-4cf0-a66b-3932639ba749

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 114/334 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55937655; called by muse, mutect2, varscan2
- NONO | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV52136490; called by muse, mutect2, varscan2
- NUP85 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1282968084, COSV55455999; called by muse, mutect2, varscan2
- RAB4A | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 10/251 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1172272102, COSV64207635; called by muse, mutect2
- SPAG5 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 109/335 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV58801180; called by muse, mutect2, varscan2
- ACSL6 | c.1885-8_1889delinsCG p.X629_splice (on ENST00000379240; = p.X654_splice on NM_015256.4 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 76/317 reads (24%) | called by pindel, varscan2*
- SHROOM4 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 144/451 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- SVEP1 | c.8657G>A p.C2886Y | Missense Mutation (SNP) | VAF 73/425 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX13B | c.411G>A p.A137= | Silent (SNP) | VAF 165/512 reads (32%) | catalogued as rs1292896996, COSV57203359; called by muse, mutect2, varscan2
- WNK2 | c.2862C>T p.P954= | Silent (SNP) | VAF 85/291 reads (29%) | catalogued as rs148099783; called by muse, mutect2, varscan2
- IGFN1 | c.1241+1168G>A | Intron (SNP) | VAF 25/422 reads (6%) | catalogued as rs569661162, COSV55173703; called by muse, mutect2
